Gene-level copy-number profile of specimen HCM-BROD-0450-C15-85M from HCMI case HCM-BROD-0450-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 52.4 years (19,140 days).
Specimen HCM-BROD-0450-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 994db9c4-e15a-4c40-a6c7-2a78f20efc56.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0450-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/85483270-316c-47b3-9e43-05383631de93

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,990; copy number 2: 40,218; copy number 3: 9,018; copy number 4: 2,561; copy number 5: 643; copy number 6: 93; copy number 7: 103; copy number 8: 169; copy number 9: 18; copy number 11: 4; copy number 12: 11; copy number 13: 9; copy number 14: 5; copy number 15: 17; copy number 17: 2; copy number 26: 9; copy number 28: 1; copy number 29: 2; copy number 30: 4; copy number 31: 9.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,099 genes in 47 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:168,695,874–169,103,276, 8 genes, copy number 5 (within-gene range 4–5): AL135926.1, AL031275.1, LINC00626, SUMO1P2, LINC00970, RPL29P7, AL031726.2, RNA5SP66.
- chr2:4,514,204–4,656,498, 2 genes, copy number 5: NPM1P48, LINC01249.
- chr2:7,383,227–9,770,341, 40 genes, copy number 5: AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1, LINC00298, AC007463.2, LINC00299, U91324.1, LINC01814, AC011747.1, SNRPEP5, ID2-AS1, ID2, KIDINS220, MBOAT2, HMGB1P25, RPL30P3, AC093904.2, AC093904.4, AC093904.3, AC093904.1, ASAP2, EIF1P7, ITGB1BP1, CPSF3, IAH1, ADAM17, AC080162.1, AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3.
- chr2:10,039,092–11,403,175, 41 genes, copy number 5: AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1, RN7SL832P, Metazoa_SRP, AC092687.2, ATP6V1C2, RNU7-138P, AC092687.3, PDIA6, RNU7-176P, LINC01954, AC092687.1, AC079587.1, KCNF1, RPL6P4, AC062028.1, C2orf50, SLC66A3, ROCK2, RNU6-1081P, AIDAP1, PPIAP60, AC099344.1, LINC00570, AC099344.2.
- chr2:11,658,178–12,702,913, 11 genes, copy number 5 (within-gene range 4–5): NTSR2, CDK8P1, AC106875.2, LPIN1, AC106875.1, AC012456.1, AC012456.2, MIR548S, MIR3681HG, MIR4262, SNORD18.
- chr2:12,411,398–12,605,145, 2 genes, copy number 5: RNU6-843P, AC096559.1.
- chr2:13,537,673–14,400,963, 3 genes, copy number 5 (within-gene range 4–5): AC073062.1, LINC00276, AC016730.1.
- chr2:14,530,941–14,650,814, 3 genes, copy number 5: Metazoa_SRP, AC011897.1, LRATD1.
- chr2:15,166,914–15,573,868, 3 genes, copy number 5: NBAS, RPS26P18, AC008278.2.
- chr2:15,801,747–15,950,981, 8 genes, copy number 5: AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P.
- chr2:16,085,222–17,800,242, 21 genes, copy number 5: AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1.
- chr2:17,877,847–22,861,884, 65 genes, copy number 5 (broad region; genes not listed).
- chr2:38,203,363–38,286,410, 3 genes, copy number 5 (within-gene range 3–5): AC009229.1, RPL7P12, GAPDHP25.
- chr2:40,097,270–41,157,555, 5 genes, copy number 5 (within-gene range 4–5): SLC8A1, AC007877.1, AC007317.1, LINC01794, HNRNPA1P57.
- chr2:42,762,481–43,132,482, 9 genes, copy number 5–6: OXER1, HAAO, FTOP1, CHORDC1P1, AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580.
- chr2:85,318,020–85,442,791, 14 genes, copy number 8: TGOLN2, Y_RNA, PEBP1P2, RETSAT, ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P.
- chr2:109,792,758–109,985,124, 5 genes, copy number 5 (within-gene range 2–5): RGPD5, LIMS3, AC013271.1, AC013268.1, AC013268.5.
- chr2:234,438,328–234,497,081, 4 genes, copy number 5: AC097713.1, LINC01891, HSPE1P9, ARL4C.
- chr5:51,275,253–54,546,586, 42 genes, copy number 5–8: AC026798.1, AC010478.1, ISL1, HMGB1P47, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1, AC008873.1, LINC01033, RPL37P25, HSPB3, SNX18.
- chr6:31,479,973–31,739,763, 43 genes, copy number 7–9: MICB-DT, MICB, Y_RNA, AL663061.1, PPIAP9, RPL15P4, MCCD1, SNORD117, SNORD84, DDX39B-AS1, ATP6V1G2, NFKBIL1, LTA, TNF, LTB, LST1, NCR3, UQCRHP1, AIF1, PRRC2A, SNORA38, MIR6832, BAG6, APOM, C6orf47, C6orf47-AS1, GPANK1, Y_RNA, CSNK2B, AL662899.2, LY6G5B, LY6G5C, ABHD16A, AL662899.1, MIR4646, LY6G6F, LY6G6F-LY6G6D, LY6G6E, LY6G6D, MPIG6B, LY6G6C, DDAH2, CLIC1.
- chr8:97,853,021–100,464,613, 58 genes, copy number 5 (within-gene range 4–5): AP002906.1, SUMO2P18, RPS23P1, MATN2, RPL30, AP003352.1, SNORA72, RNU6-703P, ERICH5, RIDA, POP1, NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1, AC018442.2, AC018442.3, COX6C, AC105328.1, RGS22, SNORD77B, AC021590.1, FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471.
- chr8:100,475,667–101,206,193, 25 genes, copy number 5–7: AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706.
- chr8:101,361,794–102,688,906, 30 genes, copy number 5–7: NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3, GRHL2, AP001207.2, AP001207.1, NCALD, AP000426.1, AP001329.1, PDCL3P2, MIR5680, AP001328.1, RRM2B, UBR5-AS1, SUMO2P19, UBR5, AP002907.1, AP002981.1, RNU6ATAC8P, HSPE1P14, RPS12P15, AP002852.1, RNU6-1224P, ODF1, POU5F1P2, KLF10, ADI1P2.
- chr8:103,021,063–103,298,772, 10 genes, copy number 6 (within-gene range 3–6): ATP6V1C1, MTND1P5, MTCO1P4, MTCO2P4, LINC01181, BAALC-AS2, BAALC, BAALC-AS1, MIR3151, AC025370.1.
- chr8:119,165,034–130,443,674, 179 genes, copy number 5–8 (broad region; genes not listed).
- chr10:42,149,310–48,119,455, 171 genes, copy number 5 (broad region; genes not listed).
- chr10:52,450,874–53,766,614, 8 genes, copy number 5 (within-gene range 3–5): LNCAROD, MBL2, Y_RNA, LINC02672, SNRPEP8, AC036101.1, RNA5SP318, AL365496.1.
- chr11:787,115–867,116, 13 genes, copy number 6: CEND1, SLC25A22, AP006621.6, PIDD1, RPLP2, SNORA52, PNPLA2, AP006621.1, CRACR2B, CD151, POLR2L, TSPAN4, AP006623.1.
- chr11:95,150,539–95,234,391, 3 genes, copy number 5: AP000787.1, SESN3, AP000787.3.
- chr11:95,571,040–95,963,624, 8 genes, copy number 5: AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1.
- chr11:97,000,274–97,259,987, 3 genes, copy number 5: MED28P5, AP001836.1, LINC02553.
- chr11:100,641,975–102,628,070, 33 genes, copy number 6–12: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1.
- chr13:105,690,429–105,797,539, 2 genes, copy number 5: AL359745.1, LINC00343.
- chr14:75,053,237–75,202,169, 8 genes, copy number 8–13: ACYP1, ZC2HC1C, NEK9, HIF1AP1, AL049780.2, TMED10, AL691403.2, RNU4ATAC14P.
- chr14:106,867,660–106,879,812, 3 genes, copy number 5: IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:87,600,526–88,100,985, 18 genes, copy number 5–6: AC092720.2, JPH3, AC010536.3, AC010536.1, KLHDC4, AC010536.2, AC126696.3, AC126696.1, SLC7A5, MIR6775, AC126696.2, CA5A, AC133539.1, AC127455.1, BANP, AC134312.4, AC134312.3, AC134312.1.
- chr17:18,426,861–18,551,705, 11 genes, copy number 6–8 (within-gene range 4–8): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:20,946,906–25,056,760, 93 genes, copy number 5–6 (broad region; genes not listed).
- chr19:27,638,483–32,072,113, 76 genes, copy number 7–31 (within-gene range 2–32) (broad region; genes not listed).
- chr20:47,209,214–47,412,327, 5 genes, copy number 5–6: ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754.

Autosomal genes at a single copy (total copy number 1): 3,134. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
